Somatic mutation profile of tumor specimen HCM-CSHL-0731-C19-06A (aliquot HCM-CSHL-0731-C19-06A-11D-A82I-36) from HCMI case HCM-CSHL-0731-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 46.5 years (16,989 days).
Specimen HCM-CSHL-0731-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2d65b4d-36fe-4207-8209-86cb1173747d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0731-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0731-C19-10A-01D-A82I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eedec70e-faf1-427b-9122-6e52dd6566fa

The open-access MAF lists 96 somatic variants for this specimen: 76 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 66, Silent 20, Nonsense Mutation 6, Frame Shift Ins 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 61/124 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 141/171 reads (82%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100053399, COSV51014574; called by muse, mutect2, varscan2
- SMAD4 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 148/178 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs377767346, CM994757, COSV61688013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 164/199 reads (82%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARAF | c.640T>A p.S214T | Missense Mutation (SNP) | VAF 584/632 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV51691221, COSV51692725, COSV51695605; called by muse, mutect2, varscan2
- ATP8B4 | c.2602C>T p.R868* | Nonsense Mutation (SNP) | VAF 63/225 reads (28%) | catalogued as rs745514384, COSV52723280; called by muse, mutect2, varscan2
- C4orf50 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 233/472 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs370415223; called by muse, mutect2, varscan2
- CFAP99 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 155/285 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.143); catalogued as rs1183359514; called by muse, mutect2, varscan2
- CHST6 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 196/227 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1242731464, COSV59999424, COSV60000035; called by muse, mutect2, varscan2
- DMGDH | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.283); catalogued as rs145775047; called by muse, mutect2, varscan2
- FOXE1 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 169/410 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as rs747177483, COSV64300771; called by muse, mutect2, varscan2
- GABRR1 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs778032711; called by muse, mutect2, varscan2
- GALNT18 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 181/426 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1370691131, COSV57144529; called by muse, mutect2, varscan2
- GRIK1 | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs775408657, COSV58714756; called by muse, mutect2, varscan2
- GRIN2A | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 137/310 reads (44%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs774039446, COSV58020621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGDCC4 | c.1894G>T p.A632S | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.789); catalogued as COSV61538816; called by muse, mutect2, varscan2
- KHDRBS3 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 66/665 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as COSV63422121; called by muse, mutect2, varscan2
- KIAA1109 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373288568; called by muse, mutect2, varscan2
- KMT2D | c.6011A>G p.Q2004R | Missense Mutation (SNP) | VAF 84/379 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as rs1419446311; called by muse, mutect2, varscan2
- MC2R | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 182/404 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs1190362792; called by muse, mutect2, varscan2
- MED12L | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768584576, COSV56395895; called by muse, mutect2, varscan2
- MGAM | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as rs368035457; called by muse, mutect2, varscan2
- MGME1 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 56/379 reads (15%) | catalogued as rs781005574; called by muse, mutect2, varscan2
- MYO1D | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 160/379 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs757145678, COSV59012237; called by muse, mutect2, varscan2
- NALCN | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 123/263 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772251231, COSV51924258; called by muse, mutect2, varscan2
- NLGN4X | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 356/389 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338500760, COSV52004121, COSV99321427; called by muse, mutect2, varscan2
- OR4K1 | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1489165075; called by muse, mutect2, varscan2
- PCBP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 191/465 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 106/391 reads (27%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2, varscan2
- PPFIA2 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs147865064; called by muse, mutect2
- REG4 | c.250A>C p.S84R | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV56653601; called by muse, mutect2, varscan2
- ROBO2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 134/226 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs746238322, COSV59903872; called by muse, mutect2, varscan2
- SELENOS | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776003975; called by muse, mutect2, varscan2
- SSX3 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 258/283 reads (91%) | catalogued as COSV53646006; called by muse, mutect2, varscan2
- TENM3 | c.4925C>T p.T1642M | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375567039; called by muse, mutect2, varscan2
- THEMIS | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 207/485 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1403938167, COSV64069387; called by muse, mutect2, varscan2
- WWP2 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 121/141 reads (86%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs760137313; called by muse, mutect2, varscan2
- ZNF189 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 130/331 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs146668775; called by muse, mutect2, varscan2
- ZNF71 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 121/432 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60147238; called by muse, mutect2, varscan2
- ADGRG4 | c.5857G>T p.E1953* | Nonsense Mutation (SNP) | VAF 289/307 reads (94%) | called by muse, mutect2, varscan2
- APC | c.875dup p.L292Ffs*4 | Frame Shift Ins (INS) | VAF 90/218 reads (41%) | called by mutect2, pindel, varscan2
- APC | c.1979del p.N660Tfs*10 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.1351T>C p.F451L | Missense Mutation (SNP) | VAF 196/444 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRSK1 | c.2190C>G p.N730K | Missense Mutation (SNP) | VAF 152/263 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CLSPN | c.3336dup p.Q1113Tfs*12 | Frame Shift Ins (INS) | VAF 70/296 reads (24%) | called by mutect2, pindel, varscan2
- ESM1 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ESPNL | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 391/822 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- HTR3A | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 63/314 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IGHM | c.267A>C p.K89N | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.42); called by muse, mutect2
- KAT6B | c.1692T>G p.S564R | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2
- KCNU1 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 98/368 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, varscan2
- KLF5 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 214/470 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KMT2D | c.2564T>C p.L855P | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2
- LRRTM1 | c.1556A>T p.E519V | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MACF1 | c.18016T>A p.F6006I (on ENST00000372915; = p.F4051I on NM_012090.5) | Missense Mutation (SNP) | VAF 15/350 reads (4%) | called by muse, mutect2
- MAGEB6 | c.726A>C p.Q242H | Missense Mutation (SNP) | VAF 433/454 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- METTL25 | c.128C>A p.T43K | Missense Mutation (SNP) | VAF 114/488 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- MYO18B | c.5656C>A p.Q1886K | Missense Mutation (SNP) | VAF 120/151 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NCAM2 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2J3 | c.826T>A p.F276I | Missense Mutation (SNP) | VAF 267/309 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PCDH11X | c.848A>C p.K283T | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- PRMT1 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PTPRF | c.5135C>A p.T1712K | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SEMA6A | c.2054A>G p.Q685R | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMYD1 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 126/324 reads (39%) | called by muse, mutect2
- SNAI2 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 507/723 reads (70%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP91 | c.592A>G p.M198V | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- SPAG9 | c.3322T>A p.L1108M (on ENST00000262013 / NM_001130528.3; = p.L1094M on NM_003971.6) | Missense Mutation (SNP) | VAF 89/356 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNGR2 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 209/537 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- TNC | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 195/465 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TNFAIP8L3 | c.474_476del p.N158del | In Frame Del (DEL) | VAF 64/309 reads (21%) | called by pindel, varscan2
- WNT4 | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 233/288 reads (81%) | SIFT tolerated (0.34); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- XIRP1 | c.3955C>A p.P1319T | Missense Mutation (SNP) | VAF 88/366 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFHX4 | c.6515T>G p.V2172G | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZMYM4 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
- ZNF620 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 177/285 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADRA2B | c.276C>T p.D92= | Silent (SNP) | VAF 294/616 reads (48%) | catalogued as COSV69787260; called by muse, mutect2, varscan2
- ATG2A | c.570C>T p.A190= | Silent (SNP) | VAF 167/405 reads (41%) | catalogued as rs746073619; called by muse, mutect2, varscan2
- CD22 | c.1293G>T p.P431= | Silent (SNP) | VAF 45/165 reads (27%) | called by muse, mutect2, varscan2
- CDYL2 | c.33G>A p.R11= | Silent (SNP) | VAF 85/101 reads (84%) | called by muse, mutect2, varscan2
- DAZAP1 | c.822T>C p.F274= | Silent (SNP) | VAF 95/169 reads (56%) | catalogued as rs748239078; called by muse, mutect2, varscan2
- EFCAB6 | c.2250C>T p.F750= | Silent (SNP) | VAF 83/175 reads (47%) | called by muse, mutect2, varscan2
- IFNA21 | c.231C>T p.I77= | Silent (SNP) | VAF 168/418 reads (40%) | catalogued as COSV66518179, COSV66518646, COSV66518665; called by muse, mutect2, varscan2
- ITGA3 | c.2154C>T p.I718= | Silent (SNP) | VAF 137/322 reads (43%) | catalogued as rs998092599, COSV50310505; called by muse, mutect2, varscan2
- LYPD4 | c.252G>A p.S84= | Silent (SNP) | VAF 59/276 reads (21%) | catalogued as rs782100732; called by muse, mutect2, varscan2
- MATR3 | c.1291C>T p.L431= | Silent (SNP) | VAF 70/112 reads (63%) | called by muse, mutect2, varscan2
- NKX2-5 | c.771G>A p.P257= | Silent (SNP) | VAF 125/475 reads (26%) | called by muse, mutect2, varscan2
- NPIPB11 | c.2517C>T p.C839= | Silent (SNP) | VAF 66/577 reads (11%) | called by muse, mutect2, varscan2
- OR7D4 | c.399G>A p.T133= | Silent (SNP) | VAF 173/290 reads (60%) | catalogued as rs748510147, COSV100432846, COSV58071293; called by muse, mutect2, varscan2
- SDK2 | c.4323G>A p.E1441= | Silent (SNP) | VAF 98/635 reads (15%) | called by muse, mutect2, varscan2
- SHOC2 | c.714T>C p.C238= | Silent (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- TOMM70 | c.114A>T p.R38= | Silent (SNP) | VAF 175/569 reads (31%) | called by muse, mutect2, varscan2
- XIRP2 | c.9285T>G p.T3095= (on ENST00000628543; = p.T3270= on NM_152381.6) | Silent (SNP) | VAF 15/367 reads (4%) | called by muse, mutect2
- ZNF500 | c.1350C>T p.T450= | Silent (SNP) | VAF 364/750 reads (49%) | catalogued as rs768459302; called by muse, mutect2
- ZNF729 | c.1377A>G p.P459= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs761245446, COSV62603962; called by muse, mutect2, varscan2
- ZNF879 | c.309C>A p.V103= | Silent (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
